Somatic mutation profile of tumor specimen TCGA-3U-A98E-01A (aliquot TCGA-3U-A98E-01A-11D-A39R-32) from TCGA case TCGA-3U-A98E, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 71.9 years (26,264 days).
Specimen TCGA-3U-A98E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13ade4c1-d4b6-4568-a148-073c55f0b1ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3U-A98E-10A (Blood Derived Normal), aliquot TCGA-3U-A98E-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf35f881-c918-4468-93e8-4c442b8be86f

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAP1 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1274254555; called by muse, mutect2, varscan2
- ANPEP | c.926T>C p.I309T | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.277); catalogued as rs368916420; called by muse, mutect2, varscan2
- COX11 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs1322877917; called by muse, mutect2, varscan2
- LRRC6 | c.1257C>A p.D419E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.493); catalogued as rs966627380; called by muse, mutect2, varscan2
- PMS2 | c.1759A>T p.S587C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.227); catalogued as rs1554297277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF331 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1246230912, COSV53479527; called by muse, mutect2, varscan2
- ASH1L | c.4990C>T p.Q1664* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- COL6A6 | c.5111G>C p.G1704A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- CXCR1 | c.1046A>G p.N349S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- H2AC8 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 98/171 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LATS2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 118/169 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, varscan2
- LATS2 | c.1777_1786del p.R593Afs*63 | Frame Shift Del (DEL) | VAF 106/167 reads (63%) | called by pindel, varscan2
- LPO | c.1036del p.Y346Mfs*52 | Frame Shift Del (DEL) | VAF 101/286 reads (35%) | called by mutect2, pindel, varscan2
- MUC1 | c.141C>G p.S47R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- NEU2 | c.832A>G p.S278G | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5F1 | c.470T>A p.M157K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- PRRG4 | c.89A>T p.H30L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SAE1 | c.99-2A>C p.X33_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- SDHD | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC38A3 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SNX19 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SOS1 | c.1527A>T p.E509D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SYTL5 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TLN2 | c.4874A>G p.N1625S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UNC5A | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB7 | c.79C>T p.L27= | Silent (SNP) | VAF 46/79 reads (58%) | called by muse, mutect2, varscan2
- FAM220A | c.321C>T p.F107= | Silent (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- GINM1 | c.780C>T p.F260= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- NALCN | c.2238G>A p.Q746= | Silent (SNP) | VAF 58/72 reads (81%) | called by muse, mutect2, varscan2
- SPRED2 | c.450C>T p.D150= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
